Somatic mutation profile of tumor specimen C3N-01828-01 (aliquot CPT0097850009) from CPTAC case C3N-01828, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 67.7 years (24,734 days).
Specimen C3N-01828-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e0d6821-193b-47b8-99c4-f45080f5b778.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01828-31 (Blood Derived Normal), aliquot CPT0097890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72cfc68b-7086-4207-9a6a-ddd677ef1b20

The open-access MAF lists 79 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 15, Frame Shift Del 8, Intron 6, Nonsense Mutation 3, Splice Region 2, 3'UTR 2, Frame Shift Ins 2, 5'Flank 2, 5'UTR 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 18/354 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65036851, COSV65039652; called by muse, mutect2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 29/177 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AL031777.2 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); catalogued as rs763562699; called by muse, mutect2, varscan2
- BRD2 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs779574195; called by muse, mutect2, varscan2
- DOCK3 | c.4271C>G p.T1424R | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.928); catalogued as COSV56510561, COSV56553480; called by muse, mutect2, varscan2
- DPRX | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.369); catalogued as rs752355371, COSV64949213; called by muse, mutect2, varscan2
- DSG4 | c.1505G>A p.R502K | Missense Mutation (SNP) | VAF 54/395 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV57396379; called by muse, mutect2, varscan2
- EVPLL | c.398C>G p.T133R | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.192); catalogued as rs1448423309; called by muse, mutect2, varscan2
- IGSF8 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.046); catalogued as rs1286923260; called by muse, mutect2, varscan2
- KMT2C | c.10721C>G p.S3574C | Missense Mutation (SNP) | VAF 49/333 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs771700205, COSV51494477; called by muse, mutect2, varscan2
- NCAM1 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs7105734; called by muse, mutect2, varscan2
- NUP155 | c.2624C>G p.S875C (on ENST00000231498 / NM_153485.3; = p.S816C on NM_004298.4) | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51528756; called by muse, mutect2, varscan2
- SDF4 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs201097851; called by muse, mutect2
- SHROOM4 | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1465211911; called by muse, mutect2, varscan2
- SRRM5 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 61/322 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV56193769; called by muse, mutect2, varscan2
- SSTR5 | c.1040C>A p.T347K | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as rs371873453; called by mutect2, varscan2
- TRAF2 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 63/479 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs148765924; called by muse, mutect2, varscan2
- UBA6 | c.3067G>T p.D1023Y | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100451720; called by muse, mutect2, varscan2
- XRRA1 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 55/383 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as rs376452507; called by muse, mutect2, varscan2
- ANKRD13A | c.917C>A p.T306N | Missense Mutation (SNP) | VAF 27/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AP2A1 | c.2823_2845del p.L942Pfs*22 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- ATR | c.7511_7514del p.T2504Mfs*11 | Frame Shift Del (DEL) | VAF 33/232 reads (14%) | called by mutect2, pindel, varscan2
- BNC2 | c.1126del p.Y376Ifs*12 | Frame Shift Del (DEL) | VAF 63/440 reads (14%) | called by mutect2, pindel, varscan2
- CC2D2A | c.2144del p.L715Cfs*3 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- CIITA | c.2353A>T p.K785* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- COQ8A | c.591C>T p.L197= | Splice Region (SNP) | VAF 49/402 reads (12%) | called by muse, mutect2, varscan2
- CYC1 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- DNAH17 | c.217_231del p.K73_V77del | In Frame Del (DEL) | VAF 30/301 reads (10%) | called by mutect2, pindel
- DYNC1I1 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 36/188 reads (19%) | called by muse, mutect2, varscan2
- EFCAB6 | c.2647del p.L883Sfs*63 | Frame Shift Del (DEL) | VAF 24/196 reads (12%) | called by mutect2, pindel, varscan2
- GNPDA1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- GPRIN1 | c.909A>T p.E303D | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GPS1 | c.1091C>A p.T364N | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GRIN1 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HS3ST6 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.8151T>C p.D2717= | Splice Region (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- MS4A14 | c.1015T>A p.S339T | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOL8 | c.1694A>C p.N565T | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NUBPL | c.20T>A p.L7Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); called by muse, mutect2
- NUF2 | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OCA2 | c.1242_1245del p.Y415Gfs*10 | Frame Shift Del (DEL) | VAF 70/604 reads (12%) | called by mutect2, pindel
- OPA3 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 44/273 reads (16%) | called by muse, mutect2, varscan2
- OSBPL11 | c.1556A>G p.Y519C | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTH | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- PTPRZ1 | c.745T>A p.F249I | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SEPTIN1 | c.152A>G p.E51G (on ENST00000321367; = p.E4G on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC10A3 | c.602_603dup p.V202Lfs*16 | Frame Shift Ins (INS) | VAF 32/224 reads (14%) | called by mutect2, pindel, varscan2
- SLC35A5 | c.606del p.D203Tfs*35 | Frame Shift Del (DEL) | VAF 61/412 reads (15%) | called by mutect2, pindel, varscan2
- SSTR5 | c.1043dup p.P349Tfs*65 | Frame Shift Ins (INS) | VAF 17/84 reads (20%) | called by mutect2, varscan2
- STAB2 | c.4901C>A p.A1634E | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- VHL | c.624_625del p.H208Qfs*47 | Frame Shift Del (DEL) | VAF 72/388 reads (19%) | called by mutect2, pindel*, varscan2
- ZNF524 | c.547G>C p.G183R | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRE1 | c.735C>A p.T245= | Silent (SNP) | VAF 34/317 reads (11%) | called by muse, mutect2, varscan2
- CLTC | c.1032T>C p.N344= | Silent (SNP) | VAF 61/370 reads (16%) | called by muse, mutect2, varscan2
- DCBLD1 | c.1191G>A p.Q397= | Silent (SNP) | VAF 36/276 reads (13%) | catalogued as COSV51639930; called by muse, mutect2, varscan2
- ERVV-2 | c.504T>C p.A168= | Silent (SNP) | VAF 18/131 reads (14%) | called by mutect2, varscan2
- H1-2 | c.384T>C p.P128= | Silent (SNP) | VAF 52/383 reads (14%) | called by muse, mutect2, varscan2
- PER1 | c.679C>T p.L227= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs568686489; called by muse, mutect2, varscan2
- PRKCG | c.1545C>T p.F515= | Silent (SNP) | VAF 77/369 reads (21%) | catalogued as COSV54725701; called by muse, mutect2, varscan2
- PRSS35 | c.1173C>T p.I391= | Silent (SNP) | VAF 25/149 reads (17%) | called by muse, mutect2, varscan2
- RBBP6 | c.2733G>A p.K911= | Silent (SNP) | VAF 40/279 reads (14%) | called by muse, mutect2, varscan2
- RBFOX1 | c.354G>C p.R118= | Silent (SNP) | VAF 29/250 reads (12%) | catalogued as rs200053144; called by muse, mutect2, varscan2
- RESF1 | c.3291C>T p.S1097= | Silent (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2, varscan2
- ROS1 | c.4398C>A p.I1466= | Silent (SNP) | VAF 34/372 reads (9%) | called by muse, mutect2
- SLF2 | c.120A>G p.R40= | Silent (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
- STC2 | c.66G>A p.A22= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- ZNF473 | c.1224T>G p.R408= | Silent (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- APLP2 | c.-65_-28del | 5'UTR (DEL) | VAF 11/150 reads (7%) | called by mutect2, pindel
- ELMO3 | c.238-19A>G | Intron (SNP) | VAF 26/174 reads (15%) | catalogued as rs370782263; called by muse, varscan2
- GP6 | c.*864T>G | 3'UTR (SNP) | VAF 22/115 reads (19%) | called by muse, mutect2, varscan2
- HAGHL | c.*123G>A | 3'UTR (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- NDUFS7 | chr19:1383797 G>A | 5'Flank (SNP) | VAF 70/448 reads (16%) | catalogued as rs1177251848; called by muse, mutect2, varscan2
- P2RX5 | chr17:3672427 A>T | 3'Flank (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159749 G>A | 5'Flank (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- SMTN | c.-80-241G>A | Intron (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- SMTN | c.51+1901C>T | Intron (SNP) | VAF 30/177 reads (17%) | catalogued as rs1455349059; called by muse, mutect2, varscan2
- SPATS2L | c.39+4011T>C | Intron (SNP) | VAF 26/233 reads (11%) | called by muse, mutect2, varscan2
- STXBP5L | c.2248+6027C>A | Intron (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- TENM4 | c.-321+38472T>C | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
